Somatic mutation profile of tumor specimen TCGA-EY-A547-01A (aliquot TCGA-EY-A547-01A-11D-A27P-09) from TCGA case TCGA-EY-A547, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 75.8 years (27,686 days).
Specimen TCGA-EY-A547-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 453f7c70-e68f-4cc4-b9e4-a8929fb02b91.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EY-A547-10A (Blood Derived Normal), aliquot TCGA-EY-A547-10A-01D-A27P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6eccff54-9e21-4a70-846f-fd538fc70eb1

The open-access MAF lists 191 somatic variants for this specimen: 139 protein-altering or splice-affecting, 49 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 102, Silent 49, Frame Shift Del 24, Frame Shift Ins 4, Nonsense Mutation 4, Splice Region 2, Splice Site 2, Intron 2, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.3704del p.G1235Vfs*95 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | catalogued as rs1364500207, COSV99979040; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 24/39 reads (62%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 67/74 reads (91%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACO2 | c.2302G>A p.A768T | Missense Mutation (SNP) | VAF 21/23 reads (91%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.746); catalogued as rs1804785, COSV53443244; called by muse, mutect2, varscan2
- ADAMTS16 | c.2459G>A p.R820Q | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748937514, COSV56992018, COSV99941221; called by muse, mutect2, varscan2
- ADAMTSL2 | c.2193C>A p.N731K | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.47); PolyPhen benign (0.021); catalogued as rs895501505; called by muse, mutect2, varscan2
- ADGRG4 | c.868A>T p.T290S | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.162); catalogued as COSV99795485; called by muse, mutect2, varscan2
- ALG13 | c.467C>G p.A156G | Missense Mutation (SNP) | VAF 84/137 reads (61%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.303); catalogued as COSV99322244; called by muse, mutect2, varscan2
- AMBRA1 | c.2240G>C p.R747P (on ENST00000458649 / NM_001367468.1; = p.R657P on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/102 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.862); catalogued as COSV100093961; called by muse, mutect2, varscan2
- ANKRD42 | c.536G>A p.C179Y | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1188546138, COSV99473817; called by muse, mutect2, varscan2
- ANO5 | c.1363C>T p.R455C | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.636); catalogued as rs200633920, COSV100201856; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANO9 | c.772-3del | Splice Region (DEL) | VAF 13/32 reads (41%) | catalogued as rs535142896; called by mutect2, pindel, varscan2
- ARHGAP4 | c.854G>A p.R285Q | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.28); catalogued as rs782715447, COSV100604047; called by muse, mutect2, varscan2
- ARL13A | c.283G>A p.V95I | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs766355429, COSV65880327; called by muse, mutect2, varscan2
- ATP1A2 | c.1501G>C p.V501L | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV63403057; called by muse, mutect2, varscan2
- AXIN1 | c.1777G>A p.A593T | Missense Mutation (SNP) | VAF 78/146 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs754163738, COSV51991458, COSV99249790; called by muse, mutect2, varscan2
- AXL | c.952T>A p.S318T | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV99996556; called by muse, mutect2, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 15/49 reads (31%) | catalogued as rs768244116; called by mutect2, pindel, varscan2
- BRD4 | c.3803C>T p.A1268V | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as rs781555424, COSV54590399; called by muse, mutect2, varscan2
- C11orf58 | c.374A>G p.D125G | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs752265677, COSV99930276; called by muse, mutect2, varscan2
- CARNS1 | c.2398C>A p.R800S | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.255); catalogued as COSV100321971; called by muse, mutect2, varscan2
- CD109 | c.1399T>A p.Y467N | Missense Mutation (SNP) | VAF 37/66 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV54645942; called by muse, mutect2, varscan2
- CD1B | c.635G>T p.G212V | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs1430198682, COSV63804968; called by muse, mutect2, varscan2
- CD248 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.027); catalogued as COSV100256595; called by muse, mutect2
- CDH22 | c.1810A>G p.S604G | Missense Mutation (SNP) | VAF 54/409 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.13); catalogued as COSV100952855; called by muse, mutect2, varscan2
- CHRDL1 | c.1049A>C p.E350A (on ENST00000372045; = p.E356A on NM_145234.4) | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.971); catalogued as COSV99488152; called by muse, mutect2, varscan2
- CNKSR2 | c.2236C>T p.R746C | Missense Mutation (SNP) | VAF 33/39 reads (85%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as rs1569272190, COSV54262591; called by muse, mutect2, varscan2
- CST1 | c.241del p.V81* | Frame Shift Del (DEL) | VAF 61/243 reads (25%) | catalogued as rs756924682; called by mutect2, pindel, varscan2
- CST3 | c.364T>A p.F122I | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as COSV100976864; called by muse, mutect2
- CUL7 | c.2155A>G p.N719D | Missense Mutation (SNP) | VAF 52/133 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs760376155, COSV99538611; called by muse, mutect2, varscan2
- DCLK2 | c.2239del p.H747Tfs*153 | Frame Shift Del (DEL) | VAF 8/16 reads (50%) | catalogued as rs751255369; called by mutect2, varscan2
- DIAPH1 | c.1591G>T p.A531S | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV99526595; called by muse, mutect2, varscan2
- DMD | c.2531A>T p.Q844L | Missense Mutation (SNP) | VAF 65/95 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV100819727; called by muse, mutect2, varscan2
- DNAH2 | c.4771G>T p.G1591C | Missense Mutation (SNP) | VAF 23/25 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101209316, COSV66723923; called by muse, mutect2, varscan2
- DRP2 | c.290T>C p.L97P | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV100871912; called by muse, mutect2, varscan2
- EBF3 | c.257G>T p.R86M | Missense Mutation (SNP) | VAF 62/121 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV100799204; called by muse, mutect2, varscan2
- EGFLAM | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.845); catalogued as rs369204325, COSV59305298; called by muse, mutect2, varscan2
- EPHA4 | c.115G>A p.V39I | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT tolerated (0.56); PolyPhen benign (0.057); catalogued as COSV99916531; called by muse, mutect2, varscan2
- EPHX4 | c.515dup p.M173Hfs*12 | Frame Shift Ins (INS) | VAF 50/104 reads (48%) | catalogued as rs765115164; called by mutect2, varscan2
- EPS8L1 | c.953A>G p.D318G (on ENST00000201647 / NM_133180.3; = p.D191G on NM_017729.3) | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs921241920, COSV99136264; called by muse, mutect2, varscan2
- ESCO1 | c.1346C>T p.T449I | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV99332271; called by muse, mutect2, varscan2
- FAM131B | c.685C>T p.Q229* | Nonsense Mutation (SNP) | VAF 17/43 reads (40%) | catalogued as COSV100578062; called by muse, mutect2, varscan2
- FAM47B | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs779361808, COSV61452630; called by muse, mutect2, varscan2
- FFAR1 | c.128T>C p.V43A | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1318921379, COSV99323234; called by muse, mutect2, varscan2
- FIGNL1 | c.428C>G p.A143G | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.058); catalogued as COSV100794896; called by muse, mutect2, varscan2
- FMNL3 | c.799G>T p.A267S | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as COSV99526312; called by muse, mutect2
- FOXN3 | c.1466A>G p.K489R (on ENST00000261302; = p.K467R on NM_005197.4) | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as COSV99726470; called by muse, mutect2, varscan2
- GNAS | c.1067G>A p.R356H | Missense Mutation (SNP) | VAF 49/55 reads (89%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV99670055; called by muse, mutect2, varscan2
- GPAM | c.415G>A p.V139I | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.185); catalogued as rs760138463, COSV100788217; called by muse, mutect2, varscan2
- GRB10 | c.1502A>G p.E501G (on ENST00000398812; = p.E455G on NM_001001549.3) | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV100240473; called by muse, mutect2, varscan2
- GRM5 | c.1906A>G p.I636V | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.333); catalogued as COSV100551962; called by muse, mutect2, varscan2
- HEMK1 | c.500G>A p.G167D | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99231740; called by muse, mutect2, varscan2
- HOMER2 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV100420359; called by muse, mutect2, varscan2
- IRS4 | c.3677C>T p.P1226L | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.235); catalogued as COSV100929417; called by muse, mutect2, varscan2
- IRX4 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 41/206 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1261260838, COSV99180801; called by muse, mutect2, varscan2
- KCNA4 | c.663del p.F221Lfs*21 | Frame Shift Del (DEL) | VAF 5/32 reads (16%) | catalogued as rs754892524; called by mutect2, pindel, varscan2
- KCNC4 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as COSV100873622; called by muse, mutect2
- KLHL31 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1333004367, COSV100911781; called by muse, mutect2, varscan2
- KRT37 | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 53/60 reads (88%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV99845477; called by muse, mutect2, varscan2
- KRT85 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV57736893; called by muse, mutect2, varscan2
- KRTAP10-3 | c.170G>A p.C57Y | Missense Mutation (SNP) | VAF 80/165 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as COSV100553582; called by muse, mutect2, varscan2
- MAFB | c.125C>A p.P42Q | Missense Mutation (SNP) | VAF 27/31 reads (87%) | SIFT tolerated (0.31); PolyPhen benign (0.062); catalogued as COSV100965044, COSV64827116; called by muse, mutect2, varscan2
- MAGI2 | c.3115_3116insA p.L1039Hfs*30 | Frame Shift Ins (INS) | VAF 15/41 reads (37%) | catalogued as COSV100834504; called by mutect2, pindel, varscan2
- MAP9 | c.104G>C p.R35P | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100250902, COSV60903979; called by muse, mutect2, varscan2
- MARCHF7 | c.1145C>A p.T382K | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as COSV99373795; called by muse, mutect2, varscan2
- MARCKS | c.980del p.P327Qfs*42 | Frame Shift Del (DEL) | VAF 12/27 reads (44%) | catalogued as rs770972906; called by mutect2, pindel, varscan2
- MCF2 | c.892C>T p.Q298* | Nonsense Mutation (SNP) | VAF 14/68 reads (21%) | catalogued as COSV100644786; called by muse, mutect2, varscan2
- MED20 | c.422A>T p.E141V | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV99539858; called by muse, mutect2, varscan2
- MMEL1 | c.1562G>A p.R521H | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs373578113; called by muse, mutect2, varscan2
- MTNR1A | c.711T>G p.F237L | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.173); catalogued as COSV100208205; called by muse, mutect2, varscan2
- MUC16 | c.13034C>G p.A4345G | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.221); catalogued as rs1460561632, COSV101199960, COSV67489629; called by muse, mutect2, varscan2
- MYH14 | c.2476C>T p.R826C | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs753356694, COSV51814526, COSV99222724; called by muse, mutect2, varscan2
- NPAS2 | c.1540C>T p.R514W | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs767945700, COSV100176208; called by muse, mutect2, varscan2
- NPY4R | c.40T>G p.S14A | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.012); catalogued as COSV100966165; called by muse, mutect2, varscan2
- OR4F6 | c.863C>G p.T288S | Missense Mutation (SNP) | VAF 24/26 reads (92%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV100186916; called by muse, mutect2, varscan2
- P3H2 | c.1425G>T p.Q475H | Missense Mutation (SNP) | VAF 41/62 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs754583836, COSV100077703; called by muse, mutect2
- P3H2 | c.1423C>G p.Q475E | Missense Mutation (SNP) | VAF 44/66 reads (67%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100077704; called by muse, mutect2
- PCDHGA9 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 47/69 reads (68%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.085); catalogued as COSV99538415; called by muse, mutect2, varscan2
- PKD1 | c.10303C>G p.R3435G (on ENST00000262304 / NM_001009944.3; = p.R3434G on NM_000296.4) | Missense Mutation (SNP) | VAF 73/166 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.072); catalogued as COSV51926418, COSV99238147; called by muse, mutect2, varscan2
- PLEKHH2 | c.1465C>A p.L489I | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99174766; called by muse, mutect2, varscan2
- PLXNB1 | c.2338C>T p.P780S | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as rs779023218, COSV99602842; called by muse, mutect2, varscan2
- PPP2CA | c.94T>A p.C32S | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as COSV99196040; called by muse, mutect2, varscan2
- PRMT2 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs770525653, COSV99388666; called by muse, mutect2, varscan2
- PTER | c.4T>C p.S2P | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV100126665; called by muse, mutect2, varscan2
- PTPRB | c.3206G>A p.S1069N | Missense Mutation (SNP) | VAF 154/321 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99717421; called by muse, mutect2, varscan2
- RB1 | c.1848del p.G617Vfs*6 | Frame Shift Del (DEL) | VAF 21/35 reads (60%) | catalogued as CM092255, COSV57309246; called by mutect2, pindel, varscan2
- RBM10 | c.1590G>T p.M530I | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100237800; called by muse, mutect2, varscan2
- RBM22 | c.607T>C p.Y203H | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.376); catalogued as COSV99556009; called by muse, mutect2, varscan2
- RCC2 | c.1355G>A p.S452N | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as rs756158591, COSV100965159; called by muse, mutect2, varscan2
- RIOK1 | c.1117G>A p.V373I | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.557); catalogued as COSV99344778; called by muse, mutect2, varscan2
- RP1 | c.2591T>C p.I864T | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as CD065760, COSV99607502; called by muse, mutect2, varscan2
- RPL24 | c.220C>G p.R74G | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as COSV101231180; called by muse, mutect2, varscan2
- RUFY4 | c.1687G>A p.A563T | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.16); PolyPhen benign (0.375); catalogued as rs760063589, COSV60248856; called by muse, mutect2, varscan2
- RXFP3 | c.574C>T p.R192W | Missense Mutation (SNP) | VAF 26/28 reads (93%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as rs201917378, COSV100347544; called by muse, mutect2, varscan2
- SACS | c.11875A>G p.T3959A | Missense Mutation (SNP) | VAF 20/22 reads (91%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.985); catalogued as COSV101207447; called by muse, mutect2, varscan2
- SDR39U1 | c.785T>A p.L262Q | Missense Mutation (SNP) | VAF 13/154 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99249712; called by muse, mutect2
- SEMA3G | c.863T>C p.L288P | Missense Mutation (SNP) | VAF 26/38 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99202341; called by muse, mutect2, varscan2
- SLCO6A1 | c.1875A>G p.I625M | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.643); catalogued as rs1394116435, COSV101134340; called by muse, mutect2, varscan2
- SMC6 | c.1228del p.I410Yfs*4 | Frame Shift Del (DEL) | VAF 42/104 reads (40%) | catalogued as rs760667210; called by mutect2, varscan2
- SPTBN4 | c.5696C>T p.A1899V | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as COSV100150919; called by muse, mutect2, varscan2
- SSMEM1 | c.239-1G>C p.X80_splice | Splice Site (SNP) | VAF 13/27 reads (48%) | catalogued as COSV99927721; called by muse, mutect2, varscan2
- STIM2 | c.1541G>A p.R514H | Missense Mutation (SNP) | VAF 66/163 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1049239912, COSV52839580, COSV52843323; called by muse, mutect2, varscan2
- TAF9B | c.481G>C p.A161P | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.981); catalogued as COSV100540671; called by muse, mutect2, varscan2
- TBC1D10C | c.960del p.A321Rfs*100 | Frame Shift Del (DEL) | VAF 44/123 reads (36%) | catalogued as rs751687887; called by mutect2, pindel, varscan2
- TBC1D17 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1226568213, COSV99680648; called by muse, mutect2, varscan2
- TBCD | c.1327G>A p.V443M | Missense Mutation (SNP) | VAF 92/95 reads (97%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as rs541763206, COSV62809102; called by muse, mutect2, varscan2
- TET1 | c.4898T>C p.V1633A | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.43); PolyPhen benign (0.02); catalogued as COSV101018247; called by muse, mutect2, varscan2
- TFE3 | c.1694G>A p.R565H | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.83); catalogued as rs782782345, COSV100252460, COSV100252555; called by muse, mutect2, varscan2
- THOC2 | c.1330C>A p.H444N | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV99833358; called by muse, mutect2, varscan2
- TIE1 | c.743del p.P248Lfs*117 | Frame Shift Del (DEL) | VAF 35/96 reads (36%) | catalogued as rs1417872933, COSV100992023; called by mutect2, pindel, varscan2
- TNS1 | c.2832C>A p.P944= | Splice Region (SNP) | VAF 36/93 reads (39%) | catalogued as COSV99410720; called by muse, mutect2, varscan2
- TP53BP2 | c.403G>A p.A135T (on ENST00000343537 / NM_001031685.3; = p.A6T on NM_005426.2) | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as COSV100636636, COSV59067022; called by muse, mutect2, varscan2
- TRPC7 | c.1547C>A p.S516* | Nonsense Mutation (SNP) | VAF 24/56 reads (43%) | catalogued as COSV100725706, COSV61456417; called by muse, mutect2, varscan2
- UBE3B | c.712C>T p.R238C | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752392755, COSV99784003; called by muse, mutect2, varscan2
- UMPS | c.1223T>A p.M408K | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV51738423, COSV99229003; called by muse, mutect2, varscan2
- UPF3A | c.798del p.E267Rfs*13 | Frame Shift Del (DEL) | VAF 21/23 reads (91%) | catalogued as rs767420916; called by mutect2, varscan2
- USP11 | c.246G>A p.W82* (on ENST00000218348; = p.W39* on NM_001371072.1) | Nonsense Mutation (SNP) | VAF 40/62 reads (65%) | catalogued as COSV99331702; called by muse, mutect2, varscan2
- VWA7 | c.2612C>T p.A871V | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs768174464, COSV100991837; called by muse, mutect2, varscan2
- WDR6 | c.2021T>G p.L674R | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV100556427; called by muse, mutect2, varscan2
- WDR86 | c.492del p.L165Ffs*3 | Frame Shift Del (DEL) | VAF 33/90 reads (37%) | catalogued as rs763559217; called by mutect2, pindel, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 23/57 reads (40%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- ZSWIM4 | c.289C>T p.R97W | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs760233986, COSV99584900; called by muse, mutect2, varscan2
- ADAM23 | c.245del p.N82Ifs*87 | Frame Shift Del (DEL) | VAF 17/47 reads (36%) | called by mutect2, pindel, varscan2
- ALX4 | c.1016del p.P339Lfs*12 | Frame Shift Del (DEL) | VAF 42/99 reads (42%) | called by mutect2, pindel, varscan2
- ARID5B | c.1490del p.I497Kfs*16 | Frame Shift Del (DEL) | VAF 9/19 reads (47%) | called by mutect2, pindel, varscan2
- BMP3 | c.1019del p.K340Rfs*17 | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | called by mutect2, pindel, varscan2
- DPPA4 | c.340-9_355del p.X114_splice | Splice Site (DEL) | VAF 18/48 reads (38%) | called by mutect2, pindel, varscan2
- KAT8 | c.916_918del p.K306del | In Frame Del (DEL) | VAF 24/97 reads (25%) | called by mutect2, pindel, varscan2
- KDM5A | c.4760dup p.V1588Gfs*9 | Frame Shift Ins (INS) | VAF 37/100 reads (37%) | called by mutect2, pindel, varscan2
- KIF15 | c.3243del p.K1081Nfs*13 | Frame Shift Del (DEL) | VAF 16/44 reads (36%) | called by mutect2, pindel, varscan2
- MRC1 | c.3473A>G p.N1158S | Missense Mutation (SNP) | VAF 114/248 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYSM1 | c.1701dup p.S568* | Frame Shift Ins (INS) | VAF 60/148 reads (41%) | called by mutect2, varscan2
- NOL6 | c.1916del p.G639Afs*10 | Frame Shift Del (DEL) | VAF 50/146 reads (34%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.1453_1457delinsT p.E485Yfs*6 (on ENST00000521381 / NM_181523.3; = p.E215Yfs*6 on NM_181504.4) | Frame Shift Del (DEL) | VAF 22/49 reads (45%) | called by pindel, varscan2*
- PRAMEF19 | c.1181T>A p.L394Q | Missense Mutation (SNP) | VAF 184/516 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRSS53 | c.108del p.K37Sfs*18 | Frame Shift Del (DEL) | VAF 35/95 reads (37%) | called by mutect2, pindel, varscan2
- SMAD7 | c.626del p.P209Lfs*115 | Frame Shift Del (DEL) | VAF 26/32 reads (81%) | called by mutect2, varscan2
- TTLL10 | c.737del p.P246Rfs*34 (on ENST00000379289 / NM_001130045.2; = p.P173Rfs*34 on NM_153254.3) | Frame Shift Del (DEL) | VAF 12/33 reads (36%) | called by mutect2, pindel
- UBE2T | c.59del p.P20Qfs*20 | Frame Shift Del (DEL) | VAF 14/37 reads (38%) | called by mutect2, pindel, varscan2
- ABCA3 | c.5088G>A p.Q1696= | Silent (SNP) | VAF 46/90 reads (51%) | catalogued as COSV100068482; called by muse, mutect2, varscan2
- ADGRG4 | c.2271C>G p.T757= | Silent (SNP) | VAF 25/81 reads (31%) | catalogued as COSV99795487, COSV99797330; called by muse, mutect2, varscan2
- AMBRA1 | c.2241C>T p.R747= (on ENST00000458649 / NM_001367468.1; = p.R657= on NM_017749.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 48/102 reads (47%) | catalogued as COSV100093957; called by muse, mutect2, varscan2
- ATP8B4 | c.2025A>T p.G675= | Silent (SNP) | VAF 44/58 reads (76%) | catalogued as COSV99463424, COSV99465490; called by muse, mutect2, varscan2
- BCKDK | c.282G>A p.L94= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV99570639; called by muse, mutect2, varscan2
- C2CD2L | c.1848T>C p.D616= | Silent (SNP) | VAF 10/91 reads (11%) | catalogued as rs746637835, COSV100371231, COSV60884000; called by muse, mutect2, varscan2
- CACNB4 | c.651G>A p.P217= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as rs370926360; called by muse, mutect2, varscan2
- CC2D2A | c.420G>A p.E140= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV101052780; called by muse, mutect2, varscan2
- COL4A6 | c.2469C>A p.I823= | Silent (SNP) | VAF 72/119 reads (61%) | catalogued as COSV100564112; called by muse, mutect2, varscan2
- CPT1C | c.1224G>A p.V408= | Silent (SNP) | VAF 25/87 reads (29%) | catalogued as COSV99773463; called by muse, mutect2, varscan2
- CUX2 | c.171T>C p.P57= | Silent (SNP) | VAF 34/79 reads (43%) | catalogued as COSV99919683; called by muse, mutect2, varscan2
- CXCR3 | c.903G>T p.S301= | Silent (SNP) | VAF 8/173 reads (5%) | catalogued as COSV101031626; called by muse, mutect2
- DENND2C | c.1701T>C p.D567= (on ENST00000393274 / NM_001256404.2; = p.D510= on NM_198459.4) | Silent (SNP) | VAF 47/95 reads (49%) | catalogued as COSV101283930; called by muse, mutect2, varscan2
- DMXL1 | c.609G>A p.R203= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV100223978; called by muse, mutect2, varscan2
- EXOC3L4 | c.387C>A p.P129= | Silent (SNP) | VAF 14/23 reads (61%) | catalogued as COSV101197610; called by muse, mutect2, varscan2
- FCHSD2 | c.513C>T p.I171= | Silent (SNP) | VAF 56/102 reads (55%) | catalogued as COSV100238434; called by muse, mutect2, varscan2
- FEM1B | c.975T>C p.H325= | Silent (SNP) | VAF 37/40 reads (93%) | catalogued as COSV100183655; called by muse, mutect2, varscan2
- FLG | c.1314A>G p.S438= | Silent (SNP) | VAF 129/272 reads (47%) | catalogued as COSV100911585; called by muse, mutect2, varscan2
- FRAS1 | c.11082C>G p.A3694= | Silent (SNP) | VAF 26/52 reads (50%) | catalogued as COSV99347090, COSV99352044; called by muse, mutect2, varscan2
- JAK2 | c.1038G>A p.K346= | Silent (SNP) | VAF 33/79 reads (42%) | catalogued as COSV101073403, COSV67578025; called by muse, mutect2, varscan2
- KLC4 | c.1596T>A p.G532= | Silent (SNP) | VAF 76/157 reads (48%) | catalogued as COSV99431942; called by muse, mutect2, varscan2
- KLHL13 | c.1041A>G p.G347= | Silent (SNP) | VAF 38/86 reads (44%) | catalogued as COSV99451641; called by muse, mutect2
- LENG1 | c.567A>G p.R189= | Silent (SNP) | VAF 46/98 reads (47%) | catalogued as COSV99651854; called by muse, mutect2, varscan2
- LRFN1 | c.139C>T p.L47= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV99952953; called by muse, mutect2, varscan2
- LRFN5 | c.1752G>A p.T584= | Silent (SNP) | VAF 38/102 reads (37%) | catalogued as rs1232236494, COSV99983900; called by muse, mutect2, varscan2
- MAN2B1 | c.1014G>A p.L338= | Silent (SNP) | VAF 42/80 reads (53%) | catalogued as COSV99666968; called by muse, mutect2, varscan2
- MDM2 | c.621A>G p.V207= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV99254552; called by muse, mutect2, varscan2
- MUC4 | c.14781C>T p.R4927= (on ENST00000463781 / NM_018406.7; = p.R691= on NM_004532.6) | Silent (SNP) | VAF 24/106 reads (23%) | catalogued as COSV100204713; called by muse, mutect2, varscan2
- NALCN | c.4551C>T p.Y1517= | Silent (SNP) | VAF 25/28 reads (89%) | catalogued as rs748173874, COSV51929902; called by muse, mutect2, varscan2
- PKHD1L1 | c.3711A>G p.L1237= | Silent (SNP) | VAF 30/118 reads (25%) | catalogued as rs952492326, COSV101006146; called by muse, mutect2, varscan2
- PPIAL4G | c.219C>T p.T73= | Silent (SNP) | VAF 91/192 reads (47%) | catalogued as rs367921294, COSV70087259; called by muse, mutect2, varscan2
- PTPRR | c.27G>A p.A9= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as rs1240856779, COSV99317536; called by muse, mutect2
- RBM10 | c.1845T>C p.Y615= | Silent (SNP) | VAF 38/71 reads (54%) | catalogued as COSV100237802; called by muse, mutect2, varscan2
- RBM47 | c.249C>T p.Y83= | Silent (SNP) | VAF 41/47 reads (87%) | catalogued as rs758272045, COSV55933120; called by muse, mutect2, varscan2
- RDX | c.1188T>C p.A396= | Silent (SNP) | VAF 47/93 reads (51%) | catalogued as rs886047647, COSV58194264; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RPUSD1 | c.255C>T p.S85= | Silent (SNP) | VAF 29/60 reads (48%) | catalogued as rs778345503, COSV50100761; called by muse, mutect2, varscan2
- SEMA3C | c.1410C>T p.G470= | Silent (SNP) | VAF 21/23 reads (91%) | catalogued as rs766668794, COSV54859816; called by muse, mutect2, varscan2
- SLC4A3 | c.201C>T p.S67= | Silent (SNP) | VAF 64/120 reads (53%) | catalogued as rs760996889, COSV99812844; called by muse, mutect2, varscan2
- SLC9A9 | c.426T>A p.I142= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as COSV100340836; called by muse, mutect2, varscan2
- SON | c.5400C>T p.H1800= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as rs201359372, COSV51658920; called by muse, mutect2, varscan2
- SPATA31A3 | c.3612T>G p.A1204= | Silent (SNP) | VAF 95/122 reads (78%) | called by muse, mutect2, varscan2
- TIMELESS | c.183A>G p.L61= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as rs1336895590, COSV99973978; called by muse, mutect2, varscan2
- TNFAIP3 | c.1398C>T p.S466= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as COSV99396730; called by muse, mutect2, varscan2
- TNXB | c.7617G>A p.S2539= (on ENST00000647633; = p.S2292= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/87 reads (40%) | catalogued as rs776795976, COSV100926326; called by muse, mutect2, varscan2
- TPPP | c.306G>A p.K102= | Silent (SNP) | VAF 11/117 reads (9%) | catalogued as COSV100862810; called by muse, mutect2, varscan2
- TRIB3 | c.336G>T p.A112= | Silent (SNP) | VAF 2/28 reads (7%) | called by muse, mutect2
- UBL4A | c.315C>T p.R105= | Silent (SNP) | VAF 17/146 reads (12%) | catalogued as rs781938597, COSV99682117; called by muse, mutect2
- ZFYVE16 | c.2304T>C p.H768= | Silent (SNP) | VAF 28/70 reads (40%) | catalogued as COSV100566390; called by muse, mutect2, varscan2
- ZMYM6 | c.3756T>C p.S1252= | Silent (SNP) | VAF 27/48 reads (56%) | catalogued as rs1263414306, COSV100593184; called by muse, mutect2, varscan2
- EEF1D | c.-7-3051C>T | Intron (SNP) | VAF 14/46 reads (30%) | catalogued as COSV100414731; called by muse, mutect2, varscan2
- KRT18P55 | n.699G>A | RNA (SNP) | VAF 24/27 reads (89%) | called by muse, mutect2, varscan2
- NACA | c.71-3189del | Intron (DEL) | VAF 6/14 reads (43%) | called by mutect2, varscan2
